Gene-level copy-number profile of tumor specimen TCGA-31-1950-01A from TCGA case TCGA-31-1950, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.9 years (28,100 days).
Specimen TCGA-31-1950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.cccc4e19-6828-4a2a-bc10-5458f4221229.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-31-1950-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3f492186-2c53-4e87-9ffe-db240a5b8017

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,400; copy number 2: 18,130; copy number 3: 20,402; copy number 4: 16,419; copy number 5: 2,431; copy number 6: 24; copy number 11: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-31-1950-01A-01D-0648-01): tumor purity 0.48, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:63,390,136–63,601,589, 5 genes, copy number 11 (within-gene range 6–11): LINC02568, AC007950.1, AC007950.2, USP3, USP3-AS1.

Autosomal genes at a single copy (total copy number 1): 790. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
